Gene-level copy-number profile of tumor specimen TCGA-DK-A2I2-01A from TCGA case TCGA-DK-A2I2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.3 years (23,116 days).
Specimen TCGA-DK-A2I2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.33acdd4a-22a9-4753-aa03-94a6622c2c06.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A2I2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd092574-4a38-4c39-80e1-4b833cf52ea4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 685; copy number 2: 16,415; copy number 3: 18,355; copy number 4: 12,131; copy number 5: 7,574; copy number 6: 2,643; copy number 7: 1,741; copy number 9: 80; copy number 10: 21; copy number 13: 46; copy number 23: 119; copy number 38: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A2I2-01A-11D-A17S-01): tumor purity 0.3, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:54,452,423–54,869,122, 5 genes: RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,012 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:109,542,799–117,804,174, 172 genes, copy number 7 (broad region; genes not listed).
- chr6:2,227,803–5,918,844, 94 genes, copy number 7 (broad region; genes not listed).
- chr6:11,607,552–17,034,396, 74 genes, copy number 9 (broad region; genes not listed).
- chr6:18,363,417–21,602,383, 38 genes, copy number 9–13: DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 13: AL136313.1.
- chr11:30,323,104–41,459,773, 137 genes, copy number 13–38 (within-gene range 4–38) (broad region; genes not listed).
- chr17:36,684,754–37,513,501, 21 genes, copy number 10: AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).
- chr21:14,818,843–15,014,430, 2 genes, copy number 7 (within-gene range 5–7): AF127577.4, LINC02246.
- chr21:14,918,534–15,627,342, 14 genes, copy number 7: AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P.
- chr21:18,022,370–18,114,904, 1 gene, copy number 7: AF130417.1.

Autosomal genes at a single copy (total copy number 1): 296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
